Gene-level copy-number profile of tumor specimen HTMCP-03-06-02437-01A from CGCI case HTMCP-03-06-02437, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2.
Specimen HTMCP-03-06-02437-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 15a535d2-ede5-4ec3-a1a8-745d3f0f9d97.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02437-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/1e06707f-47b9-4925-b9e7-08b9d01da764

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 2; copy number 2: 7,868; copy number 3: 20,933; copy number 4: 12,192; copy number 5: 5,937; copy number 6: 6,998; copy number 7: 4,236; copy number 8: 97; copy number 9: 97; copy number 11: 11; copy number 12: 2.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:629,062–686,673, 9 genes (within-gene range 0–5): MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, OR4F16.
- chr3:46,742,092–46,750,891, 1 gene (within-gene range 0–2): PRSS45P.
- chr3:46,753,045–46,798,390, 2 genes (within-gene range 0–2): PRSS43P, AC109583.2.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr6:32,517,353–32,530,287, 1 gene: HLA-DRB5.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,443 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–211,492,917, 1,743 genes, copy number 7–8 (broad region; genes not listed).
- chr1:211,635,865–248,408,020, 747 genes, copy number 7 (broad region; genes not listed).
- chr3:93,843,764–130,035,539, 597 genes, copy number 7–9 (broad region; genes not listed).
- chr3:130,081,831–198,123,232, 1,155 genes, copy number 7–8 (broad region; genes not listed).
- chr5:17,585,162–17,632,684, 13 genes, copy number 11–12: TAF11L7, AC233724.7, TAF11L8, TAF11L9, TAF11L10, AC233724.3, AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13.
- chr5:70,860,285–71,025,339, 5 genes, copy number 7: CDH12P1, SERF1A, SMN1, AC139834.1, NAIP.
- chr5:97,737,894–97,738,913, 1 gene, copy number 9: AC112203.1.
- chr7:38,239,580–38,378,804, 24 genes, copy number 9 (within-gene range 4–9): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.
- chr7:142,626,649–142,793,368, 27 genes, copy number 7: TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr7:142,801,041–142,802,748, 1 gene, copy number 7: TRBC2.
- chr9:60,914,407–63,385,117, 66 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr14:22,066,016–22,503,814, 63 genes, copy number 9 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 9: TRAC.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
